CCDI case PBCFRZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/28284138-bb53-42c0-a06e-6a2ff2b35fb9

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 11.8 years (4,303 days).

Biospecimens (3 samples)
- Sample 0DQZ3J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DQZ4G, 0DQZ4T (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
